Gene-level copy-number profile of tumor specimen TCGA-75-5122-01A from TCGA case TCGA-75-5122, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-5122-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.97130a69-a2ec-425d-8cb2-ddef2e793289.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-5122-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/042cbb5d-08a4-47cc-8976-14c51d1434f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 155; copy number 1: 15,305; copy number 2: 40,146; copy number 3: 2,335; copy number 4: 1,213; copy number 5: 185; copy number 6: 19; copy number 7: 126; copy number 8: 20; copy number 16: 41; copy number 18: 54; copy number 21: 20; copy number 24: 73; copy number 27: 128.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-5122-01A-01D-1752-01): tumor purity 0.32, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 155 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–2): PTPRD.
- chr9:8,797,135–9,803,784, 6 genes: RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1.
- chr9:21,077,104–22,128,103, 52 genes: IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:21,918,188–22,525,715, 96 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 666 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–7,391,907, 151 genes, copy number 5–7 (broad region; genes not listed).
- chr7:64,207,090–65,463,438, 53 genes, copy number 5: ZNF735, ZNF679, AC073270.1, ZNF736, TRIM60P18, AC073270.2, AC022202.1, YWHAEP1, VN1R40P, ZNF680P1, HNRNPCP7, ZNF680, BNIP3P42, AC016769.3, AC016769.1, AC016769.2, AC016769.4, AC016769.5, AC016769.6, ZNF107, BNIP3P11, MIR6839, AC091799.1, AC073349.3, ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, AC073349.5, ZNF273, AC073349.1, VN1R42P, MTDHP1, AC073210.3, ZNF117, ERV3-1, RNU6-1229P, CCT6P3, AC073210.2, SNORA22C, SNORA15B-1, AC073210.1, GTF2IP14, INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3.
- chr8:41,929,479–42,555,195, 18 genes, copy number 6: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr12:7,566,369–9,135,591, 95 genes, copy number 7 (broad region; genes not listed).
- chr12:24,993,424–27,824,382, 73 genes, copy number 24 (within-gene range 3–24) (broad region; genes not listed).
- chr12:57,693,955–60,419,293, 54 genes, copy number 18 (within-gene range 2–18): OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:61,708,259–62,279,150, 1 gene, copy number 7 (within-gene range 3–7): TAFA2.
- chr12:61,879,318–70,637,440, 197 genes, copy number 7–27 (within-gene range 4–27) (broad region; genes not listed).
- chr12:70,906,917–71,927,248, 20 genes, copy number 8: Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:72,046,149–72,057,377, 1 gene, copy number 6 (within-gene range 1–6): AC090109.1.
- chr12:128,267,403–128,707,915, 1 gene, copy number 7 (within-gene range 1–7): TMEM132C.
- chr12:128,399,978–128,439,206, 2 genes, copy number 7: AC023595.1, AC090424.1.

Autosomal genes at a single copy (total copy number 1): 13,251. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
